Somatic mutation profile of tumor specimen TCGA-BT-A20T-01A (aliquot TCGA-BT-A20T-01A-11D-A14W-08) from TCGA case TCGA-BT-A20T, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 63.6 years (23,220 days).
Specimen TCGA-BT-A20T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3bcc1549-fc1e-47da-90b0-f8fb61b689d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BT-A20T-11A (Solid Tissue Normal), aliquot TCGA-BT-A20T-11A-11D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e9a94a3-0f00-42ba-8858-df0a64f6a239

The open-access MAF lists 286 somatic variants for this specimen: 209 protein-altering or splice-affecting, 72 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 173, Silent 72, Nonsense Mutation 23, Splice Site 4, Splice Region 4, Frame Shift Del 3, 5'Flank 2, 3'UTR 1, Translation Start Site 1, Frame Shift Ins 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL2 | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 47/147 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55452713, COSV55455449; called by muse, mutect2, varscan2
- CREBBP | c.2659C>T p.Q887* | Nonsense Mutation (SNP) | VAF 42/57 reads (74%) | catalogued as rs1057520589, COSV52121083, COSV52125273, COSV52146190; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR3 | c.*194G>A | 3'UTR (SNP) | VAF 171/405 reads (42%) | catalogued as rs28931614, CM940785, CM940786, CX090489, COSV53399372, COSV99602429; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.5641G>C p.E1881Q | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV70026288, COSV70048767; called by muse, mutect2, varscan2
- ABCA13 | c.5821G>C p.E1941Q | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.402); catalogued as COSV70048770; called by muse, mutect2, varscan2
- ABCC4 | c.2807-1G>A p.X936_splice | Splice Site (SNP) | VAF 7/22 reads (32%) | catalogued as COSV65319690; called by muse, mutect2, varscan2
- ACTN4 | c.1862C>A p.S621Y | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as COSV53151543; called by mutect2, varscan2
- AFF3 | c.1999G>C p.E667Q | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV57878354; called by muse, mutect2, varscan2
- AKAP6 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs148757348; called by muse, mutect2, varscan2
- AMACR | c.18C>G p.I6M | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV59459443, COSV59461627; called by muse, mutect2, varscan2
- ANKRD34B | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58614236, COSV58614678; called by muse, mutect2
- ARHGAP12 | c.567G>T p.E189D | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.155); catalogued as COSV60966950; called by muse, mutect2, varscan2
- ARSF | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 38/46 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1264443532, COSV63841342; called by muse, mutect2, varscan2
- ASH1L | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 202/629 reads (32%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.083); catalogued as COSV64214914; called by muse, mutect2, varscan2
- ASIC2 | c.1366G>C p.E456Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV56771823, COSV99861276; called by muse, mutect2, varscan2
- ASTN1 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV56090085; called by muse, mutect2, varscan2
- ATP2A1 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV63922729; called by muse, mutect2, varscan2
- BRD8 | c.410G>C p.R137T | Missense Mutation (SNP) | VAF 60/84 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV50145938; called by muse, mutect2, varscan2
- BST1 | c.606C>G p.I202M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as COSV53949483; called by muse, mutect2, varscan2
- BVES | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 33/89 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.535); catalogued as COSV58950389; called by muse, mutect2, varscan2
- C1RL | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 67/214 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.234); catalogued as rs369851400, COSV99864692; called by muse, mutect2, varscan2
- C4orf17 | c.982C>G p.Q328E | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.852); catalogued as COSV56744912, COSV56746313; called by muse, mutect2, varscan2
- CALM1 | c.91A>G p.K31E | Missense Mutation (SNP) | VAF 57/86 reads (66%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.027); catalogued as COSV63663869; called by muse, mutect2, varscan2
- CAT | c.1479C>G p.I493M | Missense Mutation (SNP) | VAF 73/137 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV53814019; called by muse, mutect2, varscan2
- CCDC170 | c.1377C>A p.D459E | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as COSV53347391; called by muse, mutect2, varscan2
- CCDC33 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1182704923; called by muse, mutect2, varscan2
- CD19 | c.1576G>A p.E526K (on ENST00000324662 / NM_001178098.2; = p.E525K on NM_001770.6) | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781541929, COSV61190068; called by muse, mutect2, varscan2
- CD1D | c.393C>G p.F131L | Missense Mutation (SNP) | VAF 108/340 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63808750, COSV63809880; called by muse, mutect2, varscan2
- CDKN1A | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55191943; called by muse, mutect2, varscan2
- CFAP58 | c.1285C>A p.Q429K | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV57213910; called by muse, mutect2, varscan2
- COL6A3 | c.4649G>A p.G1550E | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV55078348; called by muse, mutect2, varscan2
- COPG1 | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV59117105; called by muse, mutect2, varscan2
- CRB1 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs937362854, COSV66328905; called by muse, mutect2, varscan2
- CSE1L | c.1115G>C p.R372T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53702606, COSV53705669; called by muse, mutect2, varscan2
- CSF1R | c.2178G>A p.M726I | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs899883054, COSV53836546; called by muse, mutect2, varscan2
- CTNNAL1 | c.975C>G p.I325M | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV57706044; called by muse, mutect2, varscan2
- CUL9 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV52736174; called by muse, mutect2, varscan2
- DLX3 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71547986; called by muse, mutect2
- DNAAF1 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs200440212; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJC3 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65133448; called by muse, mutect2, varscan2
- DOCK10 | c.3944G>C p.R1315T | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV51431032; called by muse, mutect2, varscan2
- DOCK4 | c.3517G>A p.E1173K | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV69855869; called by muse, mutect2, varscan2
- EIF4G3 | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.863); catalogued as rs760373741, COSV51674578; called by muse, mutect2
- EMILIN3 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs373870684; called by muse, mutect2, varscan2
- ENTPD2 | c.384C>T p.L128= | Splice Region (SNP) | VAF 14/40 reads (35%) | catalogued as COSV57076934; called by muse, mutect2, varscan2
- EPHX2 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.709); catalogued as COSV66846204; called by muse, mutect2, varscan2
- ERBB2 | c.1718C>T p.S573L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV54085340; called by muse, mutect2, varscan2
- ESRRG | c.106T>C p.S36P | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV63185090; called by muse, mutect2, varscan2
- EXT1 | c.2033A>T p.Y678F | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV65486168; called by muse, mutect2, varscan2
- FAM107B | c.100C>G p.H34D (on ENST00000378458 / NM_001320737.1; = p.H209D on NM_031453.3) | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51694506; called by muse, mutect2, varscan2
- FAM13C | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs769274515, COSV53253270; called by muse, mutect2, varscan2
- FAM174A | c.464G>C p.R155T | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57061871, COSV57066195; called by muse, mutect2, varscan2
- FBXO4 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 88/206 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV55852668, COSV55854593; called by muse, mutect2, varscan2
- FEZ2 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 102/283 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59907650; called by muse, mutect2, varscan2
- FNDC3A | c.1537G>A p.G513S (on ENST00000492622 / NM_001079673.2; = p.G457S on NM_014923.5) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); catalogued as COSV68135534; called by muse, mutect2, varscan2
- FSCN2 | c.547C>G p.R183G | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.199); catalogued as rs782118960; called by muse, mutect2, varscan2
- FTO | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as COSV67109779, COSV67114844; called by muse, mutect2, varscan2
- GABRB1 | c.490G>C p.D164H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54986031, COSV55003289; called by muse, mutect2, varscan2
- GASK1B | c.65G>C p.R22P | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV56705694, COSV56711036, COSV56712584; called by muse, mutect2, varscan2
- GGA3 | c.1498G>T p.V500F (on ENST00000537686 / NM_138619.4; = p.V467F on NM_014001.5) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.133); catalogued as COSV55459553; called by muse, mutect2, varscan2
- GJA9 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62532758; called by muse, mutect2, varscan2
- GPR55 | c.521A>T p.D174V | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV67408992; called by muse, mutect2, varscan2
- GRAP | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.269); catalogued as rs1158250940, COSV52414854; called by muse, mutect2, varscan2
- GRIN1 | c.2402G>C p.R801P | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.844); catalogued as COSV100159983, COSV59301720; called by muse, mutect2, varscan2
- GRM6 | c.2323G>A p.V775M | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs760164627, COSV51436761; called by muse, mutect2, varscan2
- H2BC13 | c.123C>G p.Y41* | Nonsense Mutation (SNP) | VAF 68/212 reads (32%) | catalogued as COSV62440590; called by muse, mutect2, varscan2
- HDLBP | c.1359G>C p.K453N | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV60502071; called by muse, mutect2, varscan2
- HEG1 | c.1466C>G p.S489* | Nonsense Mutation (SNP) | VAF 40/215 reads (19%) | catalogued as COSV60765965; called by muse, mutect2, varscan2
- HELT | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV58820681; called by muse, mutect2, varscan2
- HEXIM1 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60177787; called by muse, mutect2, varscan2
- HJURP | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as rs767657645, COSV64978806, COSV64979720; called by muse, mutect2, varscan2
- HLF | c.435G>C p.Q145H | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV56832269; called by muse, mutect2, varscan2
- IFIT3 | c.1084C>T p.Q362* | Nonsense Mutation (SNP) | VAF 41/94 reads (44%) | catalogued as rs762070127; called by muse, mutect2, varscan2
- IMPG1 | c.850C>A p.H284N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV64058267, COSV64062764; called by muse, varscan2
- INSR | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as COSV57157479; called by muse, mutect2, varscan2
- ITFG1 | c.897+2T>C p.X299_splice | Splice Site (SNP) | VAF 20/52 reads (38%) | catalogued as COSV57757913; called by muse, mutect2, varscan2
- ITIH2 | c.2104G>A p.D702N | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64435592; called by muse, mutect2, varscan2
- JAK2 | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (0.69); PolyPhen benign (0.224); catalogued as COSV67687291; called by muse, mutect2, varscan2
- KCNA10 | c.415G>C p.D139H | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756672651, COSV63905549; called by muse, mutect2, varscan2
- KDM2A | c.3058C>T p.R1020W | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV58188650; called by muse, mutect2, varscan2
- KDM6A | c.272del p.V91Gfs*9 | Frame Shift Del (DEL) | VAF 19/35 reads (54%) | catalogued as COSV65047491; called by mutect2, pindel, varscan2
- KIAA1109 | c.8182G>A p.E2728K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV52697121; called by muse, mutect2, varscan2
- KLC2 | c.751C>A p.R251= | Splice Region (SNP) | VAF 7/28 reads (25%) | catalogued as COSV57581963, COSV57584709; called by muse, mutect2, varscan2
- KMT2C | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV51423904; called by muse, mutect2, varscan2
- KRT74 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs769876624, COSV59774087; called by muse, mutect2, varscan2
- LCT | c.2152C>T p.P718S | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as COSV51553592, COSV51558962; called by muse, mutect2, varscan2
- LIG4 | c.2428C>G p.L810V | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as COSV63598314; called by muse, mutect2, varscan2
- LRRTM1 | c.1175C>T p.T392I | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.12); catalogued as COSV54447882; called by muse, mutect2, varscan2
- MAP6 | c.2335C>G p.L779V | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.243); catalogued as COSV59077910; called by muse, mutect2, varscan2
- MARK1 | c.1637C>T p.S546L | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV65068430, COSV65072244; called by muse, mutect2, varscan2
- MORC3 | c.394C>G p.Q132E | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV68689569; called by muse, mutect2, varscan2
- MRTFB | c.1771G>C p.E591Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57962609; called by muse, mutect2, varscan2
- MYO18A | c.3154G>A p.E1052K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.318); catalogued as rs1322503386, COSV62875054; called by muse, mutect2, varscan2
- MYO5B | c.5272G>C p.E1758Q | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.395); catalogued as COSV53228577; called by muse, mutect2, varscan2
- MYO7A | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as rs1269622956, CM961013; ClinVar: uncertain significance; called by muse, mutect2
- N4BP2L2 | c.955G>T p.V319L | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.034); catalogued as COSV57230597; called by muse, mutect2, varscan2
- NCF2 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 99/244 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.048); catalogued as rs760085363, COSV62317027; called by muse, mutect2, varscan2
- NCOA3 | c.1931C>G p.S644* | Nonsense Mutation (SNP) | VAF 41/108 reads (38%) | catalogued as COSV100507182, COSV100507475; called by muse, mutect2, varscan2
- NECAB2 | c.753G>C p.Q251H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs772913040, COSV59424019; called by muse, mutect2, varscan2
- NES | c.2821G>A p.E941K | Missense Mutation (SNP) | VAF 117/321 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.426); catalogued as COSV63963370; called by muse, mutect2, varscan2
- NISCH | c.4279C>T p.P1427S | Missense Mutation (SNP) | VAF 70/137 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs774006625, COSV58744213; called by muse, mutect2, varscan2
- NLRP4 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV56712294; called by muse, mutect2, varscan2
- NOA1 | c.2016G>C p.K672N | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as COSV51739092; called by muse, mutect2, varscan2
- NR3C2 | c.737C>G p.S246C | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as COSV60985824, COSV61001493; called by muse, mutect2, varscan2
- NSD1 | c.6850G>C p.E2284Q | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.028); catalogued as COSV61783812, COSV61786483; called by muse, mutect2
- NUMA1 | c.5083C>T p.R1695* | Nonsense Mutation (SNP) | VAF 17/104 reads (16%) | catalogued as rs1229344654; called by muse, mutect2, varscan2
- NUP42 | c.563G>A p.R188K | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51731574; called by muse, mutect2, varscan2
- OR10AD1 | c.625C>T p.L209F | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV59613225; called by muse, mutect2, varscan2
- OTOF | c.5275G>A p.D1759N (on ENST00000272371 / NM_194248.3; = p.D992N on NM_004802.4) | Missense Mutation (SNP) | VAF 82/195 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55508320, COSV55524105; called by muse, mutect2, varscan2
- PACS2 | c.2512C>G p.L838V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57658105; called by muse, mutect2, varscan2
- PALB2 | c.1366G>C p.E456Q | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.255); catalogued as COSV55171183; called by muse, mutect2, varscan2
- PARP4 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.307); catalogued as rs776900139, COSV67964745; called by muse, mutect2, varscan2
- PARP9 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV64452275; called by muse, mutect2, varscan2
- PASK | c.2050C>T p.P684S | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV52162416; called by muse, mutect2, varscan2
- PCDHGC3 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52758290, COSV52774105; called by muse, mutect2, varscan2
- PLCD4 | c.360G>T p.Q120H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.764); catalogued as COSV68843594; called by muse, mutect2, varscan2
- PLD5 | c.533C>T p.S178L (on ENST00000442594; = p.S116L on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs762589861, COSV59133651; called by muse, mutect2, varscan2
- PLEKHA5 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV54714585; called by muse, mutect2, varscan2
- PMFBP1 | c.2428G>A p.E810K (on ENST00000537465; = p.E805K on NM_031293.3) | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52833549; called by muse, mutect2, varscan2
- POLR2D | c.425A>G p.Y142C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55759561; called by muse, mutect2, varscan2
- PREX2 | c.3961C>T p.Q1321* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV55781821; called by muse, mutect2, varscan2
- PRMT6 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs776469766, COSV63656681; called by mutect2, varscan2
- PRR16 | c.205G>A p.D69N (on ENST00000407149 / NM_001300783.2; = p.D46N on NM_016644.2) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs1209094393, COSV65407686; called by muse, mutect2, varscan2
- PTH1R | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.192); catalogued as rs199707422, COSV57318252; called by muse, mutect2, varscan2
- PTPRB | c.976C>T p.H326Y | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as COSV54256901; called by muse, mutect2, varscan2
- PTPRN | c.2320G>T p.D774Y | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55352981; called by muse, mutect2, varscan2
- PUM1 | c.586C>G p.Q196E | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); catalogued as COSV57084071, COSV57092472; called by muse, mutect2, varscan2
- PXDN | c.2145C>A p.N715K | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.011); catalogued as COSV53248266; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3174G>C p.K1058N | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.44); catalogued as COSV54764830; called by muse, mutect2, varscan2
- RAPGEF2 | c.3452G>A p.R1151Q | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.997); catalogued as rs772043174, COSV52431374, COSV52434824; called by muse, mutect2, varscan2
- RBL2 | c.2284G>C p.V762L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV50891496; called by muse, mutect2, varscan2
- RBMX2 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 96/228 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV59730171; called by muse, mutect2, varscan2
- RFTN2 | c.439-1G>C p.X147_splice | Splice Site (SNP) | VAF 16/56 reads (29%) | catalogued as COSV54387991, COSV54394207; called by muse, mutect2, varscan2
- RGS7 | c.658A>T p.M220L | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV58564356; called by muse, mutect2, varscan2
- RPRD2 | c.2368C>T p.R790* | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as COSV64819420; called by muse, mutect2, varscan2
- RSBN1 | c.1696C>G p.R566G | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54731195, COSV54736028; called by muse, mutect2, varscan2
- SCN1A | c.5461C>G p.Q1821E (on ENST00000303395 / NM_001202435.3; = p.Q1810E on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as CM1311673, COSV57691800; called by muse, varscan2
- SDS | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as rs776668699, COSV55109346; called by muse, mutect2, varscan2
- SH3GL3 | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61062681; called by muse, mutect2, varscan2
- SIGLEC10 | c.2045G>A p.R682Q | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs763916091, COSV59482366; called by muse, mutect2, varscan2
- SLC12A9 | c.1341C>G p.F447L | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1185424483, COSV51937841; called by muse, mutect2, varscan2
- SLC22A10 | c.962G>A p.R321K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.074); catalogued as COSV60423968; called by muse, mutect2, varscan2
- SLC22A4 | c.1606G>C p.D536H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV52360750; called by mutect2, varscan2
- SLC39A8 | c.480G>T p.K160N | Missense Mutation (SNP) | VAF 72/208 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV63223138; called by muse, mutect2, varscan2
- SMARCA4 | c.2357C>A p.T786N | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60809436, COSV60811499; called by muse, mutect2, varscan2
- SPAG11B | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs201164210; called by muse, mutect2, varscan2
- SPDYE3 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.31); catalogued as COSV100193323; called by muse, mutect2, varscan2
- SPHKAP | c.4035G>C p.E1345D | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV60892206, COSV60898043; called by muse, mutect2, varscan2
- SPTBN4 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58960914; called by muse, mutect2, varscan2
- STIM2 | c.285C>T p.F95= | Splice Region (SNP) | VAF 18/94 reads (19%) | catalogued as COSV52841190; called by muse, mutect2
- STXBP5 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1411307159, COSV51651210; called by muse, mutect2, varscan2
- SUPT20H | c.317A>G p.Y106C (on ENST00000350612 / NM_001014286.3; = p.Y107C on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV62250037; called by muse, mutect2, varscan2
- SWT1 | c.800G>C p.R267T | Missense Mutation (SNP) | VAF 58/151 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV62260049; called by muse, mutect2, varscan2
- SYT10 | c.1443G>C p.W481C | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776540776, COSV57346649; called by muse, mutect2, varscan2
- SYT12 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs1026692384, COSV67355283; called by muse, mutect2, varscan2
- SYT3 | c.1307A>G p.N436S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.931); catalogued as rs778823813, COSV58899630; called by muse, mutect2, varscan2
- TAS2R39 | c.461T>C p.I154T | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV71471036; called by muse, mutect2, varscan2
- TBC1D10A | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.048); catalogued as COSV53166041, COSV53166534; called by muse, mutect2
- TCL1B | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as rs201542434, COSV61552307, COSV61552453; called by muse, mutect2, varscan2
- TFB1M | c.835A>G p.R279G | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV51645456; called by muse, mutect2, varscan2
- TFEC | c.871G>C p.D291H | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55401766, COSV55408483; called by muse, mutect2, varscan2
- TGM5 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV55012813; called by muse, mutect2, varscan2
- THADA | c.5567C>G p.S1856* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as rs757581612; called by muse, mutect2, varscan2
- THEMIS | c.1836G>C p.Q612H | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV64075045; called by muse, mutect2, varscan2
- TICAM1 | c.1749G>T p.Q583H | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV50238869, COSV50242611; called by muse, mutect2, varscan2
- TICAM1 | c.1479G>C p.E493D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as COSV50242725; called by muse, mutect2, varscan2
- TIGD5 | c.1795C>G p.L599V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV55309648; called by muse, mutect2, varscan2
- TIPARP | c.576del p.N192Kfs*15 | Frame Shift Del (DEL) | VAF 35/114 reads (31%) | catalogued as COSV55816000; called by mutect2, pindel, varscan2
- TJAP1 | c.752G>A p.S251N (on ENST00000372445 / NM_001146016.1; = p.S241N on NM_080604.3) | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52504335; called by muse, mutect2, varscan2
- TMPRSS11F | c.772C>G p.Q258E | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV62470150; called by muse, mutect2, varscan2
- TNFRSF13C | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV52170305; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.2133G>C p.K711N | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (0.31); PolyPhen benign (0.173); catalogued as COSV61459683; called by muse, mutect2, varscan2
- TRPV3 | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.197); catalogued as rs367883200, COSV56796486; called by muse, mutect2, varscan2
- TXNRD2 | c.1541G>T p.G514V | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101266026, COSV68693608; called by muse, mutect2, varscan2
- ULBP3 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 37/102 reads (36%) | catalogued as COSV66254308; called by muse, mutect2, varscan2
- UTP25 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV101530981; called by muse, mutect2
- VWA3B | c.2261G>C p.W754S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.018); catalogued as COSV68247599; called by muse, mutect2, varscan2
- WBP1 | c.73C>T p.R25* | Nonsense Mutation (SNP) | VAF 27/96 reads (28%) | catalogued as rs922167829, COSV104373725; called by muse, mutect2, varscan2
- WDR70 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV54286191; called by muse, mutect2
- ZBTB49 | c.1414A>T p.I472F | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV61926402; called by muse, mutect2, varscan2
- ZC3H12C | c.1990C>A p.H664N | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV53713695; called by muse, mutect2, varscan2
- ZDBF2 | c.6140G>A p.R2047Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as rs765117268, COSV65630877; called by muse, mutect2, varscan2
- ZFHX4 | c.8333C>T p.S2778F | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.134); catalogued as COSV51502071; called by muse, mutect2, varscan2
- ZFP57 | c.434G>T p.C145F | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.132); catalogued as COSV65307222; called by muse, mutect2, varscan2
- ZNF124 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs376157968; called by muse, mutect2, varscan2
- ZNF146 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 49/127 reads (39%) | catalogued as COSV61931099, COSV61932451; called by muse, mutect2, varscan2
- ZNF180 | c.1531C>T p.H511Y | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1426002088, COSV55424370; called by muse, mutect2, varscan2
- ZNF471 | c.126G>A p.M42I | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV57294112; called by muse, mutect2, varscan2
- ZZZ3 | c.1981-1G>C p.X661_splice | Splice Site (SNP) | VAF 40/112 reads (36%) | catalogued as COSV66236039; called by muse, mutect2, varscan2
- ABCA5 | c.2752C>T p.Q918* | Nonsense Mutation (SNP) | VAF 36/89 reads (40%) | called by muse, mutect2, varscan2
- ABRAXAS2 | c.188C>G p.S63* | Nonsense Mutation (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- BTBD11 | c.1999C>T p.Q667* (on ENST00000280758 / NM_001018072.2; = p.Q204* on NM_001017523.2) | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2
- CCZ1B | c.696C>T p.I232= | Splice Region (SNP) | VAF 24/91 reads (26%) | called by muse, mutect2, varscan2
- COL18A1 | c.4249C>T p.H1417Y (on ENST00000359759 / NM_130444.3; = p.H1182Y on NM_030582.4) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2
- GLYR1 | c.1171C>T p.Q391* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- GPS2 | c.338C>A p.S113* | Nonsense Mutation (SNP) | VAF 61/98 reads (62%) | called by muse, mutect2, varscan2
- HDAC4 | c.1759G>C p.E587Q | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.111); called by muse, mutect2
- INTS10 | c.1529G>C p.R510T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- LAMA5 | c.7609G>A p.D2537N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.021); called by muse, mutect2
- LAMB2 | c.3460C>T p.Q1154* | Nonsense Mutation (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- LRRC7 | c.1634G>A p.W545* (on ENST00000651989 / NM_001370785.2; = p.W512* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- NLRP9 | c.2821G>A p.D941N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.097); called by muse, mutect2
- POM121 | c.3633dup p.V1212Cfs*? (on ENST00000434423; = p.V947Cfs*117 on NM_172020.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- RSPH10B2 | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.034); called by mutect2, varscan2
- SLMAP | c.416C>G p.S139* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- TOPBP1 | c.3131_3132del p.K1044Rfs*12 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- TREH | c.1477C>T p.Q493* | Nonsense Mutation (SNP) | VAF 58/108 reads (54%) | called by muse, mutect2, varscan2
- TSC22D4 | c.605A>T p.E202V | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TTF2 | c.2554G>T p.E852* | Nonsense Mutation (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2, varscan2
- TTN | c.22805C>G p.S7602* (on ENST00000591111; = p.S6675* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 29/77 reads (38%) | called by muse, mutect2, varscan2
- A4GALT | c.648C>T p.L216= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV50747055; called by muse, mutect2, varscan2
- ACAN | c.9T>A p.T3= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1474930785, COSV61371257; called by muse, mutect2, varscan2
- ADAM28 | c.681C>T p.I227= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as rs267601861, COSV56106661; called by muse, mutect2, varscan2
- AGRN | c.459G>A p.V153= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV65072884; called by muse, mutect2, varscan2
- AP1G1 | c.495C>T p.I165= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV55496453; called by muse, mutect2, varscan2
- ARHGEF40 | c.4488C>T p.A1496= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV53885146; called by muse, mutect2, varscan2
- ASTN1 | c.2595G>A p.E865= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as rs550682065, COSV56090093; called by muse, mutect2, varscan2
- BIK | c.135C>T p.F45= | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as rs750206661, COSV53338797; called by muse, mutect2, varscan2
- CACHD1 | c.3255G>A p.V1085= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as COSV51561411, COSV99261118; called by muse, mutect2, varscan2
- CACNG2 | c.441G>A p.L147= | Silent (SNP) | VAF 73/174 reads (42%) | catalogued as rs1036047085, COSV55641305, COSV55642246; called by muse, mutect2, varscan2
- CD248 | c.1899C>T p.I633= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as rs773584280, COSV60938157; called by muse, mutect2, varscan2
- CDC16 | c.567C>T p.P189= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as rs766235975, COSV52962554; called by muse, mutect2, varscan2
- CREBBP | c.2499C>G p.L833= | Silent (SNP) | VAF 63/90 reads (70%) | catalogued as COSV52136690; called by muse, mutect2, varscan2
- DFFB | c.972C>T p.P324= | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as COSV59495921, COSV59498584; called by muse, mutect2, varscan2
- DNPH1 | c.240C>T p.D80= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV52736179; called by muse, mutect2, varscan2
- DPP6 | c.894G>A p.L298= (on ENST00000377770 / NM_001364500.2; = p.L236= on NM_001936.5) | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as COSV59650882; called by muse, mutect2, varscan2
- ECM2 | c.1120C>T p.L374= | Silent (SNP) | VAF 41/57 reads (72%) | catalogued as COSV60743383; called by muse, mutect2, varscan2
- EFCAB6 | c.3396G>A p.Q1132= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV53074644; called by muse, mutect2, varscan2
- EFCC1 | c.1311C>T p.L437= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV71402245; called by muse, mutect2, varscan2
- EIF3E | c.936G>A p.L312= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV55206895, COSV99623475; called by muse, mutect2, varscan2
- ENTPD2 | c.747C>G p.L249= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV57076920; called by muse, mutect2, varscan2
- EPHA5 | c.2205C>T p.N735= | Silent (SNP) | VAF 54/133 reads (41%) | catalogued as COSV56679970; called by muse, mutect2, varscan2
- FBXO43 | c.813A>G p.L271= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV71055772; called by muse, mutect2, varscan2
- FGFR1 | c.2139G>A p.L713= (on ENST00000447712 / NM_023110.3; = p.L711= on NM_015850.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV58346363; called by muse, mutect2, varscan2
- GABRR2 | c.1002C>T p.F334= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as rs572861153, COSV68764821; called by muse, mutect2, varscan2
- GTSE1 | c.2067G>C p.L689= | Silent (SNP) | VAF 43/130 reads (33%) | catalogued as COSV71890046; called by muse, mutect2, varscan2
- HIVEP1 | c.8145G>A p.V2715= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV65105802; called by muse, mutect2, varscan2
- HMCES | c.1014G>A p.L338= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV67301073; called by muse, mutect2, varscan2
- HMGCS1 | c.861G>A p.Q287= | Silent (SNP) | VAF 63/140 reads (45%) | catalogued as COSV57291971; called by muse, mutect2, varscan2
- IRX3 | c.534C>T p.F178= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV61668927; called by muse, mutect2, varscan2
- LRRC37A3 | c.2913C>G p.L971= | Silent (SNP) | VAF 40/177 reads (23%) | catalogued as COSV59764702; called by muse, mutect2, varscan2
- MAK16 | c.333G>A p.Q111= | Silent (SNP) | VAF 41/104 reads (39%) | catalogued as rs1182028048, COSV64078845; called by muse, mutect2, varscan2
- MCF2L | c.1482T>A p.A494= (on ENST00000375608; = p.A462= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV65055124; called by muse, mutect2, varscan2
- MDM2 | c.132A>G p.L44= | Silent (SNP) | VAF 48/135 reads (36%) | catalogued as COSV50705290; called by muse, mutect2, varscan2
- NAIP | c.129G>A p.Q43= | Silent (SNP) | VAF 57/182 reads (31%) | catalogued as COSV52003433; called by muse, mutect2, varscan2
- NLRP2 | c.1569G>A p.E523= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as rs1456511637, COSV54761596; called by muse, mutect2, varscan2
- NPAS2 | c.678C>T p.F226= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV59555208, COSV59563279; called by muse, mutect2, varscan2
- NSD2 | c.2628G>A p.K876= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV56397862; called by muse, mutect2, varscan2
- NUMA1 | c.1000C>T p.L334= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV61192183; called by muse, mutect2, varscan2
- OGDH | c.2526A>G p.L842= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as rs765082943, COSV56058445; called by muse, mutect2, varscan2
- OR5B2 | c.925C>T p.L309= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV56907488, COSV56910001; called by muse, mutect2, varscan2
- OR9Q2 | c.561C>G p.L187= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV61112978; called by muse, mutect2, varscan2
- OSBPL10 | c.1929G>A p.V643= | Silent (SNP) | VAF 48/87 reads (55%) | catalogued as COSV67345121; called by muse, mutect2, varscan2
- P4HTM | c.1233C>G p.V411= (on ENST00000383729 / NM_177939.3; = p.V472= on NM_177938.2) | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as rs1396742689, COSV59089610; called by muse, mutect2, varscan2
- PASK | c.2229C>G p.L743= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV52155532, COSV52162390; called by muse, mutect2, varscan2
- PCDHB2 | c.2074C>T p.L692= | Silent (SNP) | VAF 26/238 reads (11%) | catalogued as rs781826181; called by muse, mutect2, varscan2
- PCDHB3 | c.2068C>T p.L690= | Silent (SNP) | VAF 16/162 reads (10%) | called by muse, mutect2
- PCDHB9 | c.291C>T p.G97= | Silent (SNP) | VAF 32/74 reads (43%) | called by muse, mutect2, varscan2
- PCDHGA4 | c.1629G>A p.G543= | Silent (SNP) | VAF 36/156 reads (23%) | catalogued as rs748701559, COSV53998290; called by muse, mutect2, varscan2
- PDE3B | c.1467G>A p.P489= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs569220462, COSV56392181; called by muse, mutect2, varscan2
- PIGP | c.30G>A p.L10= | Silent (SNP) | VAF 44/187 reads (24%) | catalogued as rs760112626, COSV61640340; called by muse, mutect2, varscan2
- PNMA8A | c.462G>T p.L154= | Silent (SNP) | VAF 33/110 reads (30%) | catalogued as COSV58139751; called by muse, mutect2, varscan2
- POT1 | c.1473A>T p.P491= | Silent (SNP) | VAF 49/143 reads (34%) | catalogued as COSV62935623; called by muse, mutect2, varscan2
- POU2F1 | c.1686G>A p.V562= (on ENST00000541643 / NM_001365848.1; = p.V585= on NM_002697.4) | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV54826665; called by muse, mutect2, varscan2
- PSG2 | c.954C>G p.V318= | Silent (SNP) | VAF 100/265 reads (38%) | catalogued as rs1169491254, COSV61546828; called by muse, mutect2, varscan2
- RASSF9 | c.429C>T p.L143= | Silent (SNP) | VAF 95/245 reads (39%) | catalogued as COSV63436501; called by muse, mutect2, varscan2
- RBSN | c.693C>A p.I231= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as COSV53796040; called by muse, mutect2, varscan2
- REXO1 | c.2787C>T p.L929= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV50097933; called by muse, mutect2, varscan2
- RNASE9 | c.195C>T p.V65= | Silent (SNP) | VAF 49/125 reads (39%) | catalogued as COSV58881435; called by muse, mutect2, varscan2
- RPL3 | c.1176G>A p.L392= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV53366493, COSV53366949; called by muse, mutect2
- RPRD1A | c.595C>T p.L199= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV59823698; called by muse, mutect2, varscan2
- RSPH14 | c.93G>A p.L31= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV53270445, COSV99321189; called by muse, mutect2, varscan2
- SPINK9 | c.21C>G p.V7= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV64958206; called by muse, mutect2, varscan2
- TRIML2 | c.219G>C p.S73= | Silent (SNP) | VAF 28/127 reads (22%) | catalogued as COSV58718149, COSV58720451; called by muse, mutect2, varscan2
- TRPM3 | c.2244C>T p.H748= (on ENST00000357533 / NM_001366142.2; = p.H591= on NM_020952.6) | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as COSV62589450, COSV62596748; called by muse, mutect2, varscan2
- UEVLD | c.579C>T p.L193= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as rs773064736, COSV55579748; called by muse, mutect2, varscan2
- UNC79 | c.4821G>A p.L1607= (on ENST00000393151 / NM_001346218.2; = p.L1430= on NM_020818.5) | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV56398297, COSV56416782, COSV99829658; called by muse, mutect2, varscan2
- USP26 | c.537G>A p.K179= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV63709057; called by muse, mutect2, varscan2
- USP44 | c.1710C>G p.L570= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as COSV51567939; called by muse, varscan2
- UTP23 | c.60C>T p.F20= | Silent (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
- ZNF496 | c.1332C>T p.F444= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as COSV54183054; called by muse, mutect2, varscan2
- ZNF786 | c.775C>T p.L259= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV60277885; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504247 C>G | 5'Flank (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505090 C>T | 5'Flank (SNP) | VAF 22/69 reads (32%) | catalogued as rs774620441; called by muse, mutect2, varscan2
- SORCS1 | c.3371+195C>T | Intron (SNP) | VAF 37/81 reads (46%) | catalogued as rs775958828, COSV53913095; called by muse, mutect2, varscan2
- SSPOP | n.9762C>T | RNA (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
